Somatic mutation profile of tumor specimen TCGA-RC-A7SK-01A (aliquot TCGA-RC-A7SK-01A-11D-A34Z-10) from TCGA case TCGA-RC-A7SK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.7 years (21,814 days).
Specimen TCGA-RC-A7SK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 119a0565-67bc-40ef-bc98-69d8cea1d7ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A7SK-10A (Blood Derived Normal), aliquot TCGA-RC-A7SK-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a063c22a-eb2c-4002-92c6-4deb253cf56d

The open-access MAF lists 155 somatic variants for this specimen: 111 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 39, Nonsense Mutation 5, Splice Site 4, Intron 3, Frame Shift Ins 3, Frame Shift Del 2, RNA 2, Translation Start Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1399G>T p.V467F (on ENST00000404938 / NM_001163941.2; = p.V22F on NM_178559.6) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328680; called by muse, mutect2, varscan2
- ADGRV1 | c.7925A>G p.E2642G | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV67995173, COSV67997063; called by muse, mutect2
- AHCTF1 | c.4721A>G p.N1574S (on ENST00000366508; = p.N1548S on NM_015446.5) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV58255293; called by muse, mutect2, varscan2
- ANKS1B | c.2348T>C p.I783T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1314744105, COSV61375503; called by muse, mutect2, varscan2
- ANKS1B | c.1595T>C p.I532T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs746993204, COSV61375509; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1518C>A p.D506E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57752182; called by muse, mutect2, varscan2
- CASD1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1429617542, COSV99802697; called by muse, varscan2
- CCM2 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV51851317; called by muse, mutect2
- CCNB3 | c.318T>A p.N106K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV52079560; called by muse, mutect2, varscan2
- CEP57 | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57690455; called by muse, mutect2, varscan2
- CNTNAP5 | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV70511627; called by muse, mutect2, varscan2
- CR2 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV65509585; called by muse, mutect2, varscan2
- CSTF2T | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100484238; called by muse, mutect2
- DCDC2 | c.938A>C p.K313T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV65829840; called by muse, mutect2, varscan2
- DDRGK1 | c.741T>A p.N247K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV63227433; called by muse, mutect2, varscan2
- DNAJC19 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV62801190; called by muse, mutect2, varscan2
- DYNC1H1 | c.3794A>C p.K1265T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64142349; called by muse, mutect2
- DZIP3 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64313846; called by muse, mutect2, varscan2
- EFCAB13 | c.2896A>G p.K966E | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV58952591; called by muse, mutect2, varscan2
- EIF2AK4 | c.4517A>G p.N1506S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as rs754527586, COSV55472113; called by muse, mutect2, varscan2
- EMC10 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs765551966, COSV58543266; called by muse, mutect2, varscan2
- ERAP1 | c.2602T>C p.S868P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781657199, COSV57091343, COSV99701244; called by muse, mutect2, varscan2
- EXOC3L1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52048402; called by muse, mutect2, varscan2
- FBN1 | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs983129867, COSV57330158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV56122007; called by muse, mutect2, varscan2
- GMEB1 | c.1180T>C p.S394P | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53796715; called by muse, mutect2, varscan2
- GPATCH8 | c.2804A>G p.Y935C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs542607889, COSV59198383; called by muse, mutect2, varscan2
- GRIA4 | c.2163A>T p.K721N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV56919097; called by muse, mutect2, varscan2
- GRM3 | c.2567-1G>T p.X856_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV64479495; called by muse, mutect2, varscan2
- HEATR1 | c.1591A>G p.I531V | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1410513432, COSV63982759; called by muse, mutect2, varscan2
- HEG1 | c.2165C>A p.S722Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60765541; called by muse, mutect2, varscan2
- HGS | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as COSV61270290; called by muse, mutect2, varscan2
- HGS | c.1480A>T p.K494* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV61270297; called by muse, mutect2, varscan2
- HOXD1 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58924479; called by muse, mutect2
- HSPA6 | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59062317, COSV59062581; called by muse, mutect2, varscan2
- ICE1 | c.3028G>T p.V1010L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV56832261; called by muse, mutect2, varscan2
- IRAG1 | c.2234T>C p.L745S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV70213011; called by muse, mutect2, varscan2
- JAGN1 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57062922; called by muse, mutect2, varscan2
- KAT14 | c.2162A>G p.Y721C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776227052, COSV66609280; called by muse, mutect2, varscan2
- KIAA0232 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56929388; called by muse, mutect2, varscan2
- KIF25 | c.1006G>T p.V336L (on ENST00000354419 / NM_030615.2; = p.V284L on NM_005355.3) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV63028979; called by muse, mutect2, varscan2
- KLHL8 | c.308C>G p.A103G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV56749623, COSV99911310; called by muse, mutect2, varscan2
- KLRC2 | c.582T>C p.H194= | Splice Region (SNP) | VAF 21/144 reads (15%) | catalogued as COSV67900609; called by muse, mutect2, varscan2
- KRT18 | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV66316638; called by muse, mutect2, varscan2
- KTN1 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV68025558; called by muse, mutect2, varscan2
- LILRB1 | c.766C>A p.L256I (on ENST00000427581; = p.L220I on NM_006669.6) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV61121589; called by muse, varscan2
- LMNA | c.357-2A>G p.X119_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as CS165865, COSV61544046; called by muse, mutect2, varscan2
- MELK | c.1918del p.R640Dfs*2 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as COSV53202684; called by pindel, varscan2*
- MSH6 | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52287558; called by muse, mutect2, varscan2
- MSTN | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 79/135 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV53621667, COSV53622162; called by muse, mutect2, varscan2
- NAA11 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54515940; called by muse, mutect2, varscan2
- NAA15 | c.2057-2A>G p.X686_splice | Splice Site (SNP) | VAF 21/62 reads (34%) | catalogued as COSV56722600; called by muse, mutect2, varscan2
- NOCT | c.461-2A>T p.X154_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | catalogued as COSV54936939; called by muse, mutect2, varscan2
- NPSR1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.823); catalogued as COSV62207624; called by muse, mutect2, varscan2
- NRG1 | c.165C>G p.D55E (on ENST00000523534; = p.D202E on NM_013962.2) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV73065873; called by muse, mutect2
- NRM | c.248A>C p.E83A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.039); catalogued as COSV51298744; called by muse, mutect2, varscan2
- NUDCD1 | c.1188T>A p.D396E | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV53460560; called by muse, mutect2
- OSTM1 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); catalogued as COSV51971813; called by muse, mutect2, varscan2
- PANX3 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs1212145992, COSV52513836; called by muse, mutect2, varscan2
- PCDH11Y | c.2386A>G p.S796G (on ENST00000400457 / NM_032973.2; = p.S785G on NM_032971.3) | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.314); catalogued as COSV53077147; called by muse, mutect2, varscan2
- PCDHA6 | c.1879T>C p.Y627H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.101); catalogued as COSV65347468; called by muse, mutect2, varscan2
- PCDHA8 | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65340421, COSV65341310; called by muse, mutect2, varscan2
- PHLDA1 | c.32T>G p.L11W | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.208); catalogued as COSV56998268; called by muse, mutect2, varscan2
- PIK3C2A | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as COSV56406888; called by muse, mutect2, varscan2
- PLEKHH2 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56761019; called by muse, mutect2, varscan2
- PLXNA2 | c.3371A>C p.N1124T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV65444796; called by muse, mutect2, varscan2
- POTEE | c.1941A>C p.E647D | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV58236567, COSV58243948; called by muse, mutect2, varscan2
- PPP1R15B | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65816557; called by muse, mutect2
- PPP2R5D | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55151588; called by muse, mutect2, varscan2
- PSMD1 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV58083419; called by muse, mutect2
- PSMD1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV58083430; called by muse, mutect2
- RAB39A | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV57695536; called by muse, mutect2, varscan2
- RALGAPA1 | c.5797A>G p.I1933V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs779478358, COSV51896372; called by muse, mutect2, varscan2
- RCOR3 | c.381C>G p.Y127* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV65366860; called by muse, mutect2, varscan2
- RGS14 | c.142A>T p.S48C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs934048446, COSV68771994; called by muse, mutect2, varscan2
- RNF145 | c.1535G>A p.R512H (on ENST00000424310 / NM_001199383.2; = p.R540H on NM_144726.2) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1032640038, COSV50866490; called by muse, mutect2, varscan2
- RUNX1T1 | c.513A>T p.E171D (on ENST00000265814 / NM_001198628.1; = p.E144D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV56162643; called by muse, mutect2
- SCN7A | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV69274565; called by muse, mutect2, varscan2
- SEC24A | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV59749827; called by muse, mutect2, varscan2
- SLC15A2 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55200929; called by muse, mutect2, varscan2
- SMARCD2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); catalogued as rs778803525, COSV56738239, COSV56738433; called by muse, mutect2, varscan2
- SOWAHB | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV57555513; called by muse, mutect2, varscan2
- SPIC | c.190T>C p.Y64H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54692726; called by muse, mutect2, varscan2
- TAOK3 | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178825984, COSV66827725, COSV66828743; called by muse, mutect2, varscan2
- THEG | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770542115, COSV61074403; called by muse, mutect2, varscan2
- TIMP4 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV55140012; called by muse, mutect2, varscan2
- TMEM14C | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1349565156, COSV57639347; called by muse, mutect2, varscan2
- TNC | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 71/91 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV60783319; called by muse, mutect2, varscan2
- TNFRSF11B | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV52069378, COSV52074140; called by muse, mutect2
- TP53 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM942119, COSV52688040, COSV52961532, COSV53198425; called by muse, mutect2, varscan2
- TPP2 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101060309; called by muse, mutect2
- TRAPPC4 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs372565482; called by muse, mutect2, varscan2
- TTC27 | c.813G>T p.L271F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58656475; called by muse, mutect2, varscan2
- TTC38 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV66845125; called by muse, mutect2, varscan2
- TTC6 | c.314A>G p.Y105C (on ENST00000267368; = p.Y1374C on NM_001310135.3) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs757891111, COSV99941947; called by muse, mutect2, varscan2
- UBE2D3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV57664350; called by muse, mutect2, varscan2
- VAMP3 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV50012925; called by muse, mutect2, varscan2
- VN1R2 | c.786T>A p.Y262* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as rs1274214885, COSV59039657; called by muse, mutect2, varscan2
- WAC | c.838T>C p.F280L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.018); catalogued as COSV61569758; called by muse, mutect2, varscan2
- WDR17 | c.2060C>A p.T687N | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54573520; called by muse, mutect2, varscan2
- XIRP1 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752756564, COSV61141015; called by muse, mutect2, varscan2
- ZC3H14 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99193088; called by muse, mutect2, varscan2
- ZKSCAN4 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV66023166, COSV66023978; called by muse, mutect2, varscan2
- ZNF365 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as COSV67926529; called by muse, mutect2, varscan2
- CAND1 | c.2156dup p.L719Ffs*19 | Frame Shift Ins (INS) | VAF 28/58 reads (48%) | called by mutect2, pindel, varscan2
- HECTD4 | c.2484_2489del p.E828_D829del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- LMBRD1 | c.1395_1397del p.Y465_L466delins* (on ENST00000649011; = p.Y443_L444delins* on NM_018368.4) | Nonsense Mutation (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- OR4F17 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- SEC24A | c.2353dup p.Y785Lfs*13 | Frame Shift Ins (INS) | VAF 51/149 reads (34%) | called by mutect2, pindel, varscan2
- TAAR5 | c.761del p.L254Rfs*17 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel*, varscan2
- TNR | c.3491dup p.L1164Ffs*6 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- ABCB5 | c.1398G>T p.V466= (on ENST00000404938 / NM_001163941.2; = p.V21= on NM_178559.6) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV51713618; called by muse, mutect2, varscan2
- ADAD2 | c.1704C>T p.G568= (on ENST00000315906 / NM_001145400.2; = p.G650= on NM_139174.4) | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs901327385, COSV51895238; called by muse, mutect2, varscan2
- AREG | c.291T>A p.I97= | Silent (SNP) | VAF 80/229 reads (35%) | catalogued as COSV52645214; called by muse, mutect2, varscan2
- ATP10B | c.4119A>G p.T1373= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs528864040, COSV59164414; called by muse, mutect2, varscan2
- BCAN | c.129G>A p.A43= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV61259596; called by muse, mutect2, varscan2
- C1QTNF2 | c.24G>T p.P8= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV67433002; called by muse, mutect2, varscan2
- C2CD5 | c.2541A>T p.T847= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV61727624; called by muse, mutect2, varscan2
- CHRNA2 | c.405C>A p.V135= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV53559714; called by muse, mutect2
- CRTC2 | c.1821C>T p.H607= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV57845657; called by muse, mutect2, varscan2
- EDNRA | c.1248C>T p.N416= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV60100380; called by muse, mutect2, varscan2
- EPHA10 | c.2526T>C p.F842= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV57627182; called by muse, mutect2, varscan2
- FHOD1 | c.1617C>A p.L539= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV50758602, COSV50769610; called by muse, mutect2, varscan2
- FKBP7 | c.168A>G p.L56= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs773054038, COSV51847522; called by muse, mutect2
- ITPR2 | c.5301T>C p.N1767= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV67276027; called by muse, mutect2, varscan2
- KBTBD12 | c.1720T>C p.L574= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV59681951; called by muse, mutect2, varscan2
- KLB | c.1860G>T p.L620= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV57305185; called by muse, mutect2, varscan2
- KRT12 | c.1449C>G p.V483= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV52432401; called by muse, mutect2, varscan2
- LILRB1 | c.765C>A p.V255= (on ENST00000427581; = p.V219= on NM_006669.6) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61121581; called by muse, varscan2
- MFSD14A | c.978A>G p.A326= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV64515364; called by muse, mutect2, varscan2
- MROH7 | c.2058A>T p.G686= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV59877608; called by muse, mutect2, varscan2
- MYH11 | c.210G>T p.T70= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV55560364, COSV55569326; called by muse, mutect2, varscan2
- MYH7 | c.429G>A p.R143= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1469298161, COSV62523674; called by muse, mutect2, varscan2
- NBAS | c.3276G>A p.E1092= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as COSV55737403; called by muse, mutect2, varscan2
- NPC1L1 | c.1443T>C p.S481= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV56930198; called by muse, mutect2, varscan2
- NR2C1 | c.552A>G p.Q184= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs752310809, COSV58011578; called by muse, mutect2, varscan2
- OR2H1 | c.555C>A p.L185= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV65811429; called by muse, mutect2, varscan2
- OR5V1 | c.174T>A p.P58= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV65830301; called by muse, mutect2, varscan2
- PCDHB15 | c.1128G>T p.G376= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99178990; called by muse, mutect2
- PGPEP1L | c.261G>T p.V87= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV66710097; called by muse, mutect2, varscan2
- PLA2R1 | c.3375T>A p.T1125= | Silent (SNP) | VAF 71/167 reads (43%) | catalogued as COSV51786483; called by muse, mutect2, varscan2
- PSMD4 | c.513G>T p.V171= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV64394085; called by muse, mutect2, varscan2
- SETD2 | c.6903A>G p.T2301= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs774810866, COSV57451520; called by muse, mutect2, varscan2
- SNW1 | c.855C>T p.A285= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs957305852, COSV55056723; called by muse, mutect2, varscan2
- SPEG | c.3399C>T p.L1133= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV56679480; called by muse, mutect2, varscan2
- TTF1 | c.1050T>A p.P350= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV57507304; called by muse, mutect2, varscan2
- VSTM1 | c.384A>T p.S128= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV58076816; called by muse, mutect2, varscan2
- ZC3H14 | c.114G>T p.V38= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99193085; called by muse, mutect2, varscan2
- ZNF195 | c.873G>A p.E291= (on ENST00000399602 / NM_001130520.3; = p.E219= on NM_007152.5) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV50008035; called by muse, mutect2, varscan2
- ZNF211 | c.840T>C p.S280= (on ENST00000347302 / NM_198855.4; = p.S293= on NM_006385.5) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53745438; called by muse, mutect2, varscan2
- AL136982.4 | n.251C>T | RNA (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- ATP2B1 | c.3351+463A>G | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as COSV53812687; called by muse, mutect2, varscan2
- NEBL | c.164+26013G>C | Intron (SNP) | VAF 26/44 reads (59%) | catalogued as COSV65799154; called by muse, mutect2, varscan2
- OSGIN1 | n.890C>T | RNA (SNP) | VAF 10/19 reads (53%) | catalogued as COSV59676970; called by muse, mutect2, varscan2
- PIGK | c.987-6844A>G | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
